Somatic mutation profile of tumor specimen TCGA-RD-A7BS-01A (aliquot TCGA-RD-A7BS-01A-11D-A32N-08) from TCGA case TCGA-RD-A7BS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 46.1 years (16,847 days).
Specimen TCGA-RD-A7BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce15c295-20cc-4223-93c1-bdebc1b76e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A7BS-10A (Blood Derived Normal), aliquot TCGA-RD-A7BS-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5508a5df-1d8f-436b-bd02-fdc08f72c75a

The open-access MAF lists 52 somatic variants for this specimen: 34 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 16, Nonsense Mutation 2, Splice Region 2, 3'UTR 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as COSV100238742; called by muse, mutect2, varscan2
- BIRC6 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101429315; called by muse, mutect2, varscan2
- C2CD3 | c.954A>G p.S318= | Splice Region (SNP) | VAF 30/158 reads (19%) | catalogued as COSV100487625; called by muse, mutect2, varscan2
- CCDC87 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 68/537 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs141813240; called by muse, mutect2, varscan2
- CFTR | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs1175337832, COSV50054325, COSV99140654; called by muse, mutect2, varscan2
- CHRNB3 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.297); catalogued as rs1383226244, COSV51493323; called by muse, mutect2
- DOCK7 | c.4321A>C p.N1441H (on ENST00000635253 / NM_001367561.1; = p.N1410H on NM_033407.3) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99226431; called by muse, mutect2, varscan2
- DOLK | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201143469, COSV58282007; called by muse, mutect2, varscan2
- FAM47C | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as COSV63725008; called by muse, mutect2, varscan2
- FLRT3 | c.1910G>T p.R637I | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99446085; called by muse, mutect2
- GLG1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.053); catalogued as COSV99216414; called by muse, mutect2, varscan2
- HEATR5B | c.5729C>T p.S1910L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV51857965, COSV99250440; called by muse, mutect2
- KCNG1 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65367890; called by muse, mutect2, varscan2
- MAP1B | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99703065; called by muse, mutect2
- MAP2K7 | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 24/97 reads (25%) | catalogued as COSV67609537; called by muse, mutect2, varscan2
- MYLK2 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1428034327, COSV65659646; called by muse, mutect2, varscan2
- NBAS | c.6311G>A p.R2104Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs773412024, COSV55720842, COSV99029338, COSV99870509; called by muse, mutect2, varscan2
- NID1 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.415); catalogued as rs111733802, COSV51626161; called by muse, mutect2
- NRAP | c.4339T>C p.Y1447H (on ENST00000359988 / NM_001322945.2; = p.Y1412H on NM_006175.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773791836, COSV100748681; called by muse, mutect2, varscan2
- NT5C3A | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV54240454, COSV99641493; called by muse, mutect2
- PCDH19 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV99721073; called by muse, mutect2, varscan2
- RASA1 | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as COSV99171467; called by muse, mutect2, varscan2
- RNF20 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101206594; called by muse, mutect2, varscan2
- RPRM | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57989377; called by muse, mutect2, varscan2
- SCUBE2 | c.516A>G p.E172= | Splice Region (SNP) | VAF 22/165 reads (13%) | catalogued as rs1225366091, COSV100497058; called by muse, mutect2, varscan2
- SEMG2 | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV101034266; called by muse, mutect2, varscan2
- SI | c.478T>C p.F160L | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100017563; called by muse, mutect2, varscan2
- SLC36A3 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs761677518, COSV100077310; called by muse, mutect2, varscan2
- SLC8A1 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100245390, COSV100247695; called by muse, mutect2, varscan2
- SYBU | c.715G>A p.D239N (on ENST00000276646 / NM_001099754.2; = p.D238N on NM_017786.6) | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs769986186, COSV52613837; called by muse, mutect2, varscan2
- TGFBR1 | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100895484; called by muse, mutect2, varscan2
- TNFRSF13B | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs200173159, COSV55429614, COSV99892065; called by muse, mutect2, varscan2
- TRIM31 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV100946851; called by muse, mutect2
- ZNF467 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs1291340433, COSV100117924; called by muse, mutect2, varscan2
- ADAMTS2 | c.573C>T p.I191= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs774498509, COSV99206595; called by muse, mutect2, varscan2
- ADAMTS5 | c.1590G>T p.L530= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99536922; called by muse, mutect2
- C2CD6 | c.81C>G p.T27= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as COSV99634977; called by muse, mutect2
- CDC123 | c.384C>T p.S128= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs113913802; called by muse, mutect2, varscan2
- COL5A1 | c.225C>T p.Y75= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV100880716; called by muse, mutect2
- DRC7 | c.879G>A p.P293= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs772726162, COSV100395962; called by mutect2, varscan2
- EIF2S3 | c.982C>T p.L328= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- GPM6B | c.186C>T p.T62= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1267932844, COSV57422110; called by muse, mutect2, varscan2
- NLRP9 | c.2082C>T p.G694= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100243665; called by muse, mutect2, varscan2
- PCDHA6 | c.2058C>T p.A686= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as rs782441428, COSV65342532; called by muse, mutect2, varscan2
- PKD1 | c.9660G>A p.S3220= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs762713883, COSV99239311; called by muse, mutect2, varscan2
- PNPLA7 | c.3225C>T p.D1075= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs746420232, COSV53004524; called by muse, varscan2
- PTP4A3 | c.309C>T p.H103= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as COSV100267506; called by muse, mutect2, varscan2
- SLFN12 | c.1182C>T p.N394= | Silent (SNP) | VAF 35/254 reads (14%) | catalogued as COSV100513192; called by muse, varscan2
- ZFHX3 | c.2868C>T p.D956= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV51716109, COSV99215330; called by muse, mutect2, varscan2
- ZNF71 | c.1131C>A p.T377= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV100046431; called by muse, mutect2
- AGPAT4 | c.*5657C>A | 3'UTR (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100212264; called by muse, mutect2, varscan2
- MSL3 | c.1171+29G>A | Intron (SNP) | VAF 17/136 reads (13%) | catalogued as rs147621824, COSV100385124; called by muse, mutect2, varscan2
